Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7079, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7079-01A (Primary Tumor).

[page 1 of 2]
Collection Date: [REDACTED]
Hospital of Origin:
Copy to:

QC Pathologist:

[REDACTED] TCGA-HC-7079

FINAL PATHOLOGIC DIAGNOSIS:

A. Pelvic lymph node dissection: Four benign hyperplastic lymph nodes.

B. Radical prostatectomy: Carcinoma.

Tumor Characteristics:

1). Histologic type: Adenocarcinoma, conventional type.

2). Gleason Grade:

a. Primary pattern:

3/5.

b. Secondary pattern:

4/5.

c. Score: 7/10.

3). Tumor involves: Both lobes.

4). Seminal vesicle involvement: No.

5). Extracapsular tumor extension:

Present by perineural invasion, mid left posterior region.

6). Lymphovascular space invasion: Not identified.

7). Perineural space invasion:

Present.

8). High grade PIN: Not identified.

Surgical Margin Status:

1). Bladder neck: Negative.

2). Apical (inferior): Negative.

3). Inked prostatic margin: Within 0.1 cm. mid left posterior region.

Lymph Node status

1). Total number of lymph nodes examined: Four.

2). Number of lymph nodes with metastatic tumor: None.

Other Findings:

1). Frozen section correlation statement: None.

2). Other: Severe chronic prostatitis.

3). pTNM stage: pT3a, N0, Mx

[page 2 of 2]
COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Pelvic lymph node

B. Prostate

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

GROSS DESCRIPTION:

A. The container is labeled _____ is a 3.5 x 3.2 x 1.4 cm mass of nodular yellow adipose tissue. On section and palpation four lymph nodes are identified ranging from 0.3 x 0.2 x 0.1 cm to 3.4 x 0.9 x 0.5 cm. The nodes are entirely submitted as follows: 1. One whole node; 2. One node bisected; 3 and 4. One node sectioned; 5 and 6. One node sectioned. 1-6.

B. The container is labeled _____ is a 28 gram previously inked, sectioned and sampled radical prostatectomy specimen received for research, 4.5 x 3.2 x 2.9 cm. The right side is inked yellow and the left side black. The cut surface displays a pale yellow area of discoloration in the left posterior aspect of the mid level, 1.0 cm in greatest dimension. It abuts the inked margin. The seminal vesicles together measure 5.8 x 1.5 x 0.6 cm each is uninvolved by lesion.

Representative sections are submitted as follows: 1 and 2. Apical margin; 3. Vesicle margin; 4. Distal left lateral; 5. Distal right lateral; 6. Distal right posterior; 7. Distal left posterior; 8. Mid left lateral; 9. Mid right lateral; 10. Mid right posterior; 11. Mid left posterior; 12. Proximal left lateral; 13. Proximal right lateral; 14. Proximal right posterior; 15. Proximal left posterior; 16. Origin of seminal vesicle; 17. Representative left seminal vesicle; 18. Representative right seminal vesicle.

_____ 1-18. Two cassettes for research are labeled _____

INTRA-PROCEDURE CONSULTATION:

Source: NCI Genomic Data Commons file e44e6cad-fa3c-4617-b6a4-1c2fd6274695 (TCGA-HC-7079.8E42FCE1-33E7-45E1-B8E9-2FAF5A02766D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).